Somatic mutation profile of tumor specimen TCGA-DD-AAEG-01A (aliquot TCGA-DD-AAEG-01A-11D-A38X-10) from TCGA case TCGA-DD-AAEG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.8 years (21,853 days).
Specimen TCGA-DD-AAEG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aacfb2b3-2f1f-4664-b074-2a1195788183.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEG-10A (Blood Derived Normal), aliquot TCGA-DD-AAEG-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc769e8b-915b-4283-b4ee-fba46c2a11f8

The open-access MAF lists 117 somatic variants for this specimen: 93 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 22, Splice Region 3, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 3, Intron 2, In Frame Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7039A>G p.T2347A (on ENST00000272895 / NM_173076.3; = p.T2029A on NM_015657.3) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV99788966; called by muse, mutect2
- AKAP5 | c.669T>G p.I223M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV100277903; called by muse, mutect2, varscan2
- ALPK1 | c.1571G>C p.G524A | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99453405; called by muse, mutect2, varscan2
- ANK2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100000393; called by muse, mutect2, varscan2
- ANKRD50 | c.1008G>C p.W336C | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101538911; called by muse, mutect2, varscan2
- ARHGAP44 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1015683361, COSV99310327; called by muse, mutect2, varscan2
- ARID1A | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.161); catalogued as COSV100250736; called by muse, mutect2, varscan2
- ASH2L | c.1468A>G p.I490V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs539322046, COSV99166943; called by muse, mutect2, varscan2
- AVPR1A | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV100146802; called by muse, mutect2, varscan2
- BAHCC1 | c.7700A>C p.Q2567P | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100311308; called by muse, mutect2, varscan2
- BLMH | c.1002C>G p.S334R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99913060; called by muse, mutect2
- BMX | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100564366; called by muse, mutect2, varscan2
- CCN3 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 26/277 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as rs778838879, COSV52383450, COSV52383987; called by muse, mutect2
- CD46 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.563); catalogued as COSV100522813; called by muse, mutect2, varscan2
- CHD6 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV100497932, COSV58563243; called by muse, mutect2
- CHD9 | c.5712A>T p.E1904D | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99528875; called by muse, mutect2
- COL4A2 | c.2600A>G p.D867G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.739); catalogued as COSV100847280; called by muse, mutect2, varscan2
- COL5A3 | c.3553T>C p.S1185P | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99318404; called by muse, mutect2, varscan2
- COPB2 | c.2416G>A p.V806I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs201811724, COSV100168997; called by muse, mutect2, varscan2
- CTNND1 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100649930; called by muse, mutect2, varscan2
- DCST1 | c.461A>C p.Q154P | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99792864; called by muse, mutect2
- DDX11 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs772152833, COSV99299200; called by muse, mutect2, varscan2
- DDX50 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV101007213; called by muse, mutect2, varscan2
- DHX9 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 18/191 reads (9%) | catalogued as COSV100841292; called by muse, mutect2
- DMD | c.5084T>A p.I1695N | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1228213218, COSV100818673; called by muse, mutect2
- DNAH1 | c.3479A>T p.Q1160L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101325090; called by muse, mutect2, varscan2
- DNMT3B | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs537913125, COSV52420357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP3 | c.1818T>A p.N606K | Missense Mutation (SNP) | VAF 23/278 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs779807969, COSV100847693; called by muse, mutect2
- EHBP1L1 | c.4544G>T p.S1515I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100442071, COSV58573891; called by muse, mutect2
- EIF2AK4 | c.1853T>C p.V618A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99774299; called by muse, mutect2
- EPB41L5 | c.1001A>G p.H334R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99758432; called by muse, mutect2, varscan2
- FGD3 | c.1328G>T p.R443I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100490456; called by muse, mutect2, varscan2
- FLI1 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.816); catalogued as COSV100793517; called by muse, mutect2, varscan2
- FYCO1 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV99945330; called by muse, mutect2, varscan2
- GCC1 | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.043); catalogued as COSV100365450; called by muse, mutect2, varscan2
- GLCE | c.1279A>C p.T427P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.943); catalogued as COSV99962184; called by muse, mutect2, varscan2
- GPAT2 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs777443244, COSV64003378; called by muse, mutect2, varscan2
- GPRC5C | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 63/178 reads (35%) | catalogued as COSV100702833; called by muse, mutect2, varscan2
- IL1R1 | c.992-2A>G p.X331_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99292464; called by muse, mutect2, varscan2
- IL9R | c.1087C>G p.P363A | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1027332393, COSV99729500; called by muse, mutect2
- KCNA1 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1359358525, COSV101230107, COSV101230165, COSV101230395; called by muse, mutect2, varscan2
- KCNS1 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100067119; called by muse, mutect2, varscan2
- KEAP1 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407483, COSV99408045; called by muse, mutect2, varscan2
- KIF22 | c.1765C>A p.R589S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV99360943; called by muse, mutect2, varscan2
- KRTAP19-4 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs973143755, COSV61858411; called by muse, mutect2, varscan2
- LATS1 | c.2729T>C p.L910S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99485505; called by muse, mutect2, varscan2
- LEMD3 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100384229; called by muse, mutect2, varscan2
- LMO7 | c.2901T>A p.D967E (on ENST00000357063; = p.D648E on NM_005358.5) | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV100412695; called by muse, mutect2, varscan2
- LUZP4 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 221/598 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as COSV100904839; called by muse, mutect2, varscan2
- MAN2A2 | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs767864216, COSV100847792; called by muse, mutect2, varscan2
- MGA | c.8852C>G p.T2951S (on ENST00000219905 / NM_001164273.1; = p.T2742S on NM_001080541.2) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99579051; called by muse, mutect2, varscan2
- MYO18B | c.7285C>A p.P2429T | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122947, COSV59139732; called by muse, mutect2, varscan2
- NELL2 | c.1608T>G p.I536M | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100419034; called by muse, mutect2
- NGFR | c.983-2A>T p.X328_splice | Splice Site (SNP) | VAF 20/135 reads (15%) | catalogued as COSV99412753; called by muse, mutect2, varscan2
- NINJ1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV100966611; called by muse, mutect2, varscan2
- NKX2-2 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV101010524, COSV101010577; called by muse, mutect2, varscan2
- NSD2 | c.1404G>T p.R468S | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100372962; called by muse, mutect2, varscan2
- OR2B11 | c.638T>A p.V213E | Missense Mutation (SNP) | VAF 150/211 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100275564; called by muse, mutect2, varscan2
- PCDH7 | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs1355679466, COSV100687779; called by muse, mutect2, varscan2
- PDGFC | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV99924952; called by muse, mutect2
- PEAR1 | c.1290G>A p.T430= | Splice Region (SNP) | VAF 12/76 reads (16%) | catalogued as rs754907654, COSV99440887; called by muse, mutect2, varscan2
- PLA2G4A | c.837A>T p.L279F | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100820460; called by muse, mutect2
- PLCH1 | c.4115C>A p.T1372K (on ENST00000340059 / NM_001130960.2; = p.T1364K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV100396011; called by muse, mutect2, varscan2
- PLEKHG7 | c.1139A>G p.Y380C | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV100760064; called by muse, mutect2
- PLOD2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV51462912, COSV99282522; called by muse, mutect2, varscan2
- PNN | c.768A>G p.I256M | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as rs1474333256, COSV99397092; called by muse, mutect2
- PPP4R3A | c.2308G>T p.G770* (on ENST00000554943 / NM_001366432.1; = p.G757* on NM_001284280.1) | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100465800; called by muse, mutect2, varscan2
- PWWP3B | c.1033T>A p.F345I | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100531049; called by muse, mutect2, varscan2
- QSOX1 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV100852827; called by muse, mutect2
- RBM42 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs78375138, COSV99386921; called by muse, mutect2, varscan2
- RHCE | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 147/201 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99603837; called by muse, mutect2, varscan2
- RNF111 | c.2587A>G p.I863V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV100788850; called by muse, mutect2, varscan2
- RPA1 | c.588G>A p.K196= | Splice Region (SNP) | VAF 42/169 reads (25%) | catalogued as rs770743630, COSV99627781; called by muse, mutect2, varscan2
- SEMA6D | c.2959G>A p.V987I (on ENST00000316364 / NM_153618.2; = p.V925I on NM_020858.2) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as rs774623143, COSV100316646; called by muse, mutect2, varscan2
- SEMG2 | c.1040_1042del p.S347del | In Frame Del (DEL) | VAF 39/174 reads (22%) | catalogued as rs762335360; called by mutect2, pindel, varscan2
- SIK2 | c.948G>A p.E316= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as COSV100516032; called by muse, mutect2, varscan2
- SPATA12 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.548); catalogued as COSV100534665; called by muse, mutect2, varscan2
- SYN1 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99927255; called by muse, mutect2, varscan2
- SYNE2 | c.6222G>A p.M2074I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as COSV100647097; called by muse, mutect2, varscan2
- TNIP2 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs201862092, COSV59569770; called by muse, mutect2
- TOP2B | c.1857del p.W619* (on ENST00000264331 / NM_001330700.2; = p.W614* on NM_001068.3) | Frame Shift Del (DEL) | VAF 37/300 reads (12%) | catalogued as COSV51970558; called by mutect2, pindel, varscan2
- TRPM8 | c.1653+1G>A p.X551_splice | Splice Site (SNP) | VAF 25/85 reads (29%) | catalogued as rs187799320, COSV100223770; called by muse, mutect2, varscan2
- UBE2H | c.449C>G p.T150R | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); catalogued as COSV100842435; called by muse, mutect2, varscan2
- UNC13D | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs774248632, COSV99256239; called by muse, mutect2, varscan2
- USH2A | c.2875G>A p.V959I | Missense Mutation (SNP) | VAF 26/612 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV100231335; called by muse, mutect2
- USPL1 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV99687115; called by muse, mutect2, varscan2
- WDR36 | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.849); catalogued as rs1445451204, COSV101540786; called by muse, mutect2
- YJEFN3 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1449845860, COSV99388962, COSV99389277; called by muse, mutect2
- ZNF774 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV100586251; called by muse, mutect2, varscan2
- HMCN1 | c.15550del p.T5184Pfs*5 | Frame Shift Del (DEL) | VAF 126/237 reads (53%) | called by mutect2, pindel, varscan2
- KDELR3 | c.634_645del p.M212_*215delext*9 | Nonstop Mutation (DEL) | VAF 21/58 reads (36%) | called by mutect2, pindel, varscan2
- KPNA3 | c.386del p.P129Lfs*11 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- NR2F2 | c.652_675del p.R218_E225del | In Frame Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ALOX12B | c.1299C>T p.Y433= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100046750; called by muse, mutect2, varscan2
- ANKRD17 | c.7506A>T p.R2502= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV100428765; called by muse, mutect2, varscan2
- BCDIN3D | c.12C>T p.P4= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV100445483; called by muse, mutect2, varscan2
- BCL2L12 | c.219G>A p.R73= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV99880946; called by muse, mutect2, varscan2
- CARS1 | c.1293G>T p.L431= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99542260; called by muse, mutect2, varscan2
- DOP1B | c.552C>A p.A184= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV101215162; called by muse, mutect2, varscan2
- FAM193B | c.1392G>A p.L464= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs371452748; called by muse, mutect2, varscan2
- FBXO10 | c.402T>C p.I134= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99446376; called by muse, mutect2, varscan2
- FLG2 | c.4992G>T p.G1664= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV101165690; called by muse, mutect2
- HNRNPC | c.9C>T p.S3= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100192984; called by muse, mutect2, varscan2
- LANCL2 | c.414G>T p.R138= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV54651432, COSV99635002; called by muse, mutect2, varscan2
- MASP1 | c.399C>G p.A133= | Silent (SNP) | VAF 122/282 reads (43%) | catalogued as COSV99396919; called by muse, varscan2
- MROH7 | c.288C>A p.I96= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100273158; called by muse, mutect2, varscan2
- MS4A2 | c.105A>G p.S35= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99627123; called by mutect2, varscan2
- RBM39 | c.66G>A p.L22= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV99488348; called by muse, mutect2
- RTTN | c.5517A>G p.E1839= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs761470498, COSV99731519; called by muse, mutect2, varscan2
- SEMA3A | c.750T>C p.N250= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs774084495, COSV99545785; called by muse, mutect2, varscan2
- SPICE1 | c.1626G>A p.K542= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55625194; called by muse, mutect2, varscan2
- TFAP2C | c.564C>T p.H188= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1379019762, COSV99571364; called by muse, mutect2, varscan2
- TMC8 | c.756C>T p.F252= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as COSV100531111; called by muse, mutect2, varscan2
- ZIC3 | c.450A>T p.P150= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV99798595; called by muse, mutect2, varscan2
- ZNF674 | c.1290C>T p.V430= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV101345028; called by muse, mutect2
- DST | c.4297-2115dup | Intron (INS) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- OFCC1 | n.556+3433A>T | Intron (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
